Somatic mutation profile of tumor specimen TCGA-DF-A2KS-01A (aliquot TCGA-DF-A2KS-01A-11D-A18P-09) from TCGA case TCGA-DF-A2KS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3.
Specimen TCGA-DF-A2KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffa8aa54-3ae4-4254-a379-8658644f665b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KS-10A (Blood Derived Normal), aliquot TCGA-DF-A2KS-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e54bc963-92f5-4daf-8fde-6f69c5bcafed

The open-access MAF lists 122 somatic variants for this specimen: 98 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 20, Frame Shift Del 6, In Frame Del 4, Splice Site 3, Nonsense Mutation 3, 3'UTR 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 33/49 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as rs770976719, COSV53973069; called by muse, mutect2, varscan2
- ALOX15B | c.633T>A p.N211K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101205574; called by muse, mutect2, varscan2
- ARC | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100751674; called by muse, mutect2, varscan2
- ASH1L | c.1052T>A p.V351E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV100853194, COSV64211641; called by muse, mutect2, varscan2
- ATG12 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.343); catalogued as rs372619984; called by muse, mutect2, varscan2
- BICDL2 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV99560444; called by muse, mutect2, varscan2
- BNIP3L | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66077891; called by muse, mutect2, varscan2
- CARF | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100247518; called by mutect2, varscan2
- CAVIN4 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs536624756, COSV100293143; called by muse, mutect2, varscan2
- CEP83 | c.1793A>T p.E598V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100352695; called by muse, mutect2
- CFAP47 | c.5228A>G p.N1743S | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100545029; called by muse, mutect2, varscan2
- CHRNA6 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs910018042, COSV99373084; called by muse, mutect2, varscan2
- CLEC4C | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100665380; called by muse, mutect2, varscan2
- CNDP1 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV100722212; called by muse, mutect2, varscan2
- COL4A5 | c.1443C>A p.C481* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV60359207; called by muse, mutect2, varscan2
- COPZ1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.186); catalogued as rs774080901, COSV50432613; called by muse, mutect2, varscan2
- DHX30 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100819971, COSV100820125; called by muse, mutect2, varscan2
- DOT1L | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as rs376474660, COSV67112914; called by muse, mutect2, varscan2
- EIF3B | c.1543T>C p.C515R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100703583; called by muse, mutect2, varscan2
- ERCC6L | c.816T>G p.D272E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100559017; called by muse, mutect2, varscan2
- F13B | c.647T>C p.L216S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100803209; called by muse, mutect2, varscan2
- FAM122B | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761402998, COSV99980152; called by muse, mutect2, varscan2
- FCRLA | c.373T>G p.W125G (on ENST00000367959; = p.W102G on NM_032738.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375731; called by muse, mutect2, varscan2
- FFAR3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs376071323; called by muse, mutect2, varscan2
- FREM1 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs371148891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT2 | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100795516; called by muse, mutect2, varscan2
- GRIP2 | c.2502A>T p.Q834H (on ENST00000619221; = p.Q737H on NM_001080423.4) | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99817028; called by muse, mutect2, varscan2
- GSTA1 | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV100575463; called by muse, mutect2, varscan2
- GUCY2F | c.3288A>C p.R1096S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99484616; called by muse, mutect2, varscan2
- HMCN1 | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144448119; called by muse, mutect2, varscan2
- HSD17B10 | c.192+2T>A p.X64_splice | Splice Site (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99394883; called by muse, mutect2, varscan2
- IL17F | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs144854652, COSV100277289; called by muse, mutect2, varscan2
- IL17RE | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99924754; called by mutect2, varscan2
- IQCN | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs138028745; called by muse, mutect2, varscan2
- ITPR1 | c.3619C>T p.R1207W (on ENST00000354582; = p.R1192W on NM_002222.7) | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56987767; called by muse, mutect2, varscan2
- KIAA1549 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1454514826, COSV99650023; called by muse, mutect2, varscan2
- MAGEC3 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1464925848, COSV100024983; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50497745; called by muse, mutect2, varscan2
- MCM3AP | c.379T>G p.F127V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV99386559; called by muse, mutect2, varscan2
- MMS22L | c.2852A>C p.K951T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99246247; called by muse, mutect2
- NUP133 | c.1073C>G p.A358G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV99772644; called by muse, mutect2, varscan2
- OR4D9 | c.434T>A p.I145N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100259728; called by muse, mutect2, varscan2
- OR6C76 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100093990; called by muse, mutect2, varscan2
- OSBPL2 | c.620G>C p.W207S (on ENST00000313733 / NM_144498.4; = p.W195S on NM_014835.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100569166; called by muse, mutect2, varscan2
- P2RX6 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.825); catalogued as COSV100298551; called by muse, mutect2, varscan2
- PAPPA2 | c.3871G>A p.E1291K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100867652; called by muse, mutect2, varscan2
- PCDHA7 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs1554135772, COSV65343760, COSV65346769; called by muse, mutect2, varscan2
- PCDHA9 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as rs782596330, COSV65326310; called by muse, mutect2, varscan2
- PEX19 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV100926921; called by muse, mutect2
- PIP5K1B | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99598171; called by muse, mutect2
- PLCG2 | c.1190C>G p.S397W | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100842103, COSV63867705; called by muse, mutect2, varscan2
- PLD1 | c.2610A>G p.I870M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100577741; called by muse, mutect2
- POGLUT2 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs763402149, COSV65683165; called by muse, mutect2, varscan2
- POLR3B | c.616T>C p.S206P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99943137; called by muse, varscan2
- PPP1R12A | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99700062; called by muse, mutect2, varscan2
- PRSS21 | c.735C>G p.N245K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs560512459, COSV99135469; called by muse, mutect2, varscan2
- PSG2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs1271619391, COSV100283386; called by muse, mutect2, varscan2
- PTPRT | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61753667, COSV61996547; called by muse, mutect2, varscan2
- RBP3 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782095820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REEP5 | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as rs1363931116, COSV99809566; called by muse, mutect2, varscan2
- RHBDD2 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99138201; called by muse, mutect2, varscan2
- RIMS1 | c.3358T>G p.L1120V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.977); catalogued as rs1237700419, COSV99324762; called by muse, mutect2
- SAMD9L | c.4224del p.K1408Nfs*10 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as rs759143613, COSV59085428; called by mutect2, pindel, varscan2
- SFXN3 | c.893T>G p.I298R | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99827390; called by muse, mutect2, varscan2
- SIRT4 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as rs201272192; called by muse, mutect2, varscan2
- SLC14A2 | c.163T>G p.S55A | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99675162; called by muse, mutect2, varscan2
- SLC26A8 | c.2780G>A p.R927H | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs371431327; called by muse, mutect2, varscan2
- SLC9A5 | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100237133; called by muse, mutect2, varscan2
- SMC1A | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782176647, CM101868, COSV59129751, COSV59132016; called by muse, mutect2, varscan2
- SOGA1 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs759723501, COSV52932002; called by muse, mutect2, varscan2
- SPIN4 | c.118A>T p.I40F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100633322; called by muse, mutect2, varscan2
- SRSF6 | c.709C>G p.R237G | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs748702139, COSV99719645, COSV99719794; called by muse, mutect2, varscan2
- ST14 | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99598548; called by muse, varscan2
- SV2A | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs782353989, COSV100974939, COSV64965262; called by muse, mutect2, varscan2
- TAF7 | c.847A>T p.K283* | Nonsense Mutation (SNP) | VAF 39/73 reads (53%) | catalogued as COSV100514914; called by muse, mutect2, varscan2
- TAF7 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57666173; called by muse, mutect2, varscan2
- TAS2R38 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV101516359; called by muse, mutect2, varscan2
- THOC2 | c.3962C>T p.T1321M | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99832889; called by muse, mutect2, varscan2
- TMTC2 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV58261131; called by muse, mutect2, varscan2
- TRIP4 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187200758, COSV99974390; called by muse, mutect2, varscan2
- TRRAP | c.1012A>T p.I338F | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs1237622683, COSV100722127; called by muse, mutect2, varscan2
- USP35 | c.2473G>C p.D825H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100416337; called by muse, mutect2
- VSTM1 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV100618693; called by muse, mutect2, varscan2
- ZBTB33 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV58533906; called by muse, mutect2, varscan2
- ZCWPW2 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101074590; called by muse, mutect2, varscan2
- ZNF165 | c.547T>A p.C183S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV101055846; called by muse, mutect2, varscan2
- ADARB1 | c.2074_2082del p.I692_K694del (on ENST00000360697 / NM_001346687.2; = p.I652_K654del on NM_001112.4) | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- EPAS1 | c.30_45del p.S10Rfs*33 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- ESPL1 | c.1174_1197del p.S392_Q399del | In Frame Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel
- GLYR1 | c.1631del p.M544Sfs*86 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- HERC2 | c.13643_13648del p.S4548_L4550delinsM | In Frame Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- OR2T1 | c.607_608del p.V203Ffs*89 | Frame Shift Del (DEL) | VAF 48/119 reads (40%) | called by pindel, varscan2
- PIK3R1 | c.1781_1787del p.L594Cfs*66 (on ENST00000521381 / NM_181523.3; = p.L324Cfs*66 on NM_181504.4) | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | called by mutect2, pindel, varscan2
- PTEN | c.286_290dup p.Q97Hfs*4 | Frame Shift Ins (INS) | VAF 40/56 reads (71%) | called by mutect2, varscan2
- SEMA5A | c.433-7_446del p.X145_splice | Splice Site (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- SLX4 | c.110_118del p.S37_K39del | In Frame Del (DEL) | VAF 30/58 reads (52%) | called by mutect2, pindel, varscan2
- VSIG1 | c.555_568+2del | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- ATP11A | c.3219G>A p.G1073= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV52106874; called by muse, mutect2, varscan2
- BCL11A | c.2253C>G p.L751= (on ENST00000335712 / NM_001365609.1; = p.L785= on NM_022893.4) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100185022; called by muse, mutect2, varscan2
- BMP10 | c.93T>C p.P31= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99770305; called by muse, mutect2, varscan2
- C5 | c.2604G>T p.S868= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV99797318; called by muse, mutect2, varscan2
- CPAMD8 | c.2562G>A p.V854= (on ENST00000651564; = p.V807= on NM_015692.5) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101488431; called by muse, mutect2, varscan2
- DPM1 | c.273A>G p.P91= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs766462970, COSV65373691; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN3 | c.8223C>T p.I2741= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs374334624; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL7 | c.495C>T p.N165= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1213344060, COSV61641008; called by muse, mutect2, varscan2
- G2E3 | c.777G>A p.Q259= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99249386; called by muse, mutect2, varscan2
- HEG1 | c.3624G>A p.Q1208= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100230163; called by muse, mutect2, varscan2
- HR | c.1878T>A p.G626= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100455685; called by muse, mutect2, varscan2
- MAGEC3 | c.36C>A p.T12= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100024986, COSV53578806; called by muse, mutect2, varscan2
- NXF3 | c.1047G>A p.L349= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs773569670, COSV67704874; called by muse, mutect2, varscan2
- PCDHGA8 | c.1713T>A p.G571= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV99532807; called by muse, mutect2, varscan2
- PRDM9 | c.1041T>A p.I347= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV99689909; called by muse, mutect2, varscan2
- PSRC1 | c.534C>T p.C178= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100883475; called by muse, mutect2
- RNF125 | c.339G>A p.R113= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99470416; called by muse, mutect2, varscan2
- SEC61A1 | c.147C>G p.P49= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV99684735, COSV99685024; called by muse, mutect2, varscan2
- SPIB | c.624G>A p.L208= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99569822; called by muse, mutect2, varscan2
- ZNF211 | c.36G>T p.P12= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99560108; called by muse, varscan2
- C8orf31 | n.616G>C | RNA (SNP) | VAF 28/44 reads (64%) | called by muse, mutect2, varscan2
- HCG27 | n.414G>C | RNA (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.*1G>C | 3'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99691666; called by muse, mutect2, varscan2
- SLC35A3 | c.*189C>G | 3'UTR (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100924643; called by muse, mutect2, varscan2
